CCDI case PBBLFW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0f3fdafa-85d6-4a82-a154-90342698d879

Demographics
Sex at birth: male; Race: black or african american; Vital status: Dead.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.3 years (1,925 days).

Biospecimens (3 samples)
- Sample 0DCBIS: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCBIU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCBJ8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
